CCDI case PBBPLU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/aeee5742-1da9-44bc-980e-d2563a4b3e34

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.9 years (3,969 days).

Biospecimens (3 samples)
- Sample 0DE0QS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE0R3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE0TY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
